Somatic mutation profile of tumor specimen TCGA-06-5414-01A (aliquot TCGA-06-5414-01A-01D-1486-08) from TCGA case TCGA-06-5414, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.7 years (22,527 days).
Specimen TCGA-06-5414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e930349-840b-4beb-b57f-24bfcde13405.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5414-10A (Blood Derived Normal), aliquot TCGA-06-5414-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c36c15e-7a32-4d95-ae89-c35f4392a7d5

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.13); catalogued as rs558198391, COSV56988858; called by muse, mutect2, varscan2
- ATG4D | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs776817919, COSV58763724; called by muse, mutect2, varscan2
- CPZ | c.1858C>T p.R620W (on ENST00000360986 / NM_001014447.3; = p.R609W on NM_003652.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs143690050; called by muse, mutect2, varscan2
- CYP4B1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs765862813, COSV54726059, COSV99597430; called by muse, mutect2
- DPPA4 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 79/204 reads (39%) | catalogued as COSV59512400, COSV59512654; called by muse, mutect2, varscan2
- FNDC3B | c.3029G>A p.G1010E | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61049356; called by muse, mutect2, varscan2
- GABRA6 | c.347C>A p.T116N | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780224018, COSV50893282; called by muse, mutect2, varscan2
- HCK | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV52947004; called by muse, mutect2, varscan2
- KCNB2 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73052433; called by muse, mutect2, varscan2
- KEL | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | catalogued as COSV62337708; called by muse, mutect2, varscan2
- KRT13 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs746117318, COSV55839059; called by muse, mutect2, varscan2
- LRRC55 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs778274252, COSV73006966; called by muse, mutect2
- MEGF8 | c.7438G>A p.V2480M (on ENST00000251268 / NM_001271938.2; = p.V2413M on NM_001410.3) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs766625279, COSV52085873; called by mutect2, varscan2
- NWD1 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs139109286; called by muse, varscan2
- OLFML1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as rs750542053, COSV61402547; called by muse, mutect2, varscan2
- PCDHGB2 | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV53893048; called by muse, mutect2, varscan2
- PHYHIP | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV58689388; called by muse, mutect2, varscan2
- PPARA | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as rs1205309412, COSV53081277; called by muse, mutect2, varscan2
- SFTPC | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750172249, COSV59346191; called by muse, mutect2, varscan2
- SLC39A9 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50363570; called by muse, mutect2, varscan2
- TCF12 | c.821del p.R274Pfs*2 | Frame Shift Del (DEL) | VAF 38/243 reads (16%) | catalogued as COSV51003175; called by mutect2, pindel, varscan2
- ZNF215 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 66/217 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs192913397, COSV53492228; called by muse, mutect2, varscan2
- ZNF665 | c.1027G>A p.V343I (on ENST00000600412; = p.V408I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs375884834, COSV67214236; called by muse, mutect2, varscan2
- USP2 | c.1062-2del p.X354_splice | Splice Site (DEL) | VAF 22/68 reads (32%) | called by mutect2, pindel, varscan2
- ADAMTS16 | c.1176T>C p.C392= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as COSV57006350; called by muse, mutect2, varscan2
- DIAPH3 | c.1689T>A p.P563= (on ENST00000400324 / NM_001042517.2; = p.P300= on NM_030932.3) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99934232; called by muse, mutect2
- LRP5 | c.4224G>A p.Q1408= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV104397236, COSV53723431; called by muse, mutect2, varscan2
- OR4P4 | c.918G>T p.L306= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV58920744, COSV58923543; called by muse, mutect2, varscan2
- SGO2 | c.657A>G p.L219= | Silent (SNP) | VAF 67/189 reads (35%) | catalogued as COSV63417959; called by muse, mutect2, varscan2
- SLITRK1 | c.333G>T p.L111= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV65677488; called by muse, mutect2, varscan2
- TIMD4 | c.1086C>A p.L362= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV50859959; called by muse, mutect2
- TMEM63B | c.507C>T p.S169= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs145356402, COSV99442217; called by muse, mutect2, varscan2
- TUSC3 | c.690T>G p.G230= | Silent (SNP) | VAF 105/321 reads (33%) | catalogued as COSV65886690; called by muse, mutect2, varscan2
